EXCEPTIONAL_RESPONDERS case ER-B0FX — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46c3400f-ff27-4650-ad97-30b4961801cf

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1971; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 41.3 years (15,089 days); Year of diagnosis: 2012; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Days to last follow up: 1,917 days (5.2 years); Days to best overall response: 314 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 266 days; Days to treatment end: 391 days (1.1 years).
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 266 days; Days to treatment end: 356 days.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 293 days; Days to treatment end: 1,028 days (2.8 years).

Follow-up (1 entry)
- Days to follow up: 1,917 days (5.2 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,917 days (5.2 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0FX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0FX-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
